Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A6NN, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A6NN-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date:
Result status:
Result title: Surgical Pathology Report
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Left kidney cancer

Specimen

#1 Left kidney tumor

Gross Examination

#1 Left kidney tumor: Received in the fresh state is a spherical piece of soft, tan tissue roughly 2.8 x 3.0 x 3.0 cm. Along one edge of the specimen is a thin rim of pale brown tissue roughly 2.5 x 0.5 x 0.1 cm. The tumor has a bright golden yellow appearance with areas of cystic degeneration. It is enclosed by a 0.1 cm pseudocapsule. With the expressed written consent of the patient, a portion of tissue is donated to the The remaining tissue is sampled for Frozen Section and permanent section as follows: "FSA-E", perpendicular sections of tumor and normal appearing kidney (presumed surgical margin); "F", additional section of tumor.

Frozen Section Diagnosis

#1 LEFT KIDNEY TUMOR, EXCISIONAL BIOPSY (IFS): RENAL CELL CARCINOMA (CLEAR CELL TYPE). TUMOR IS 0.1-0.2 CM FROM RENAL SURGICAL MARGIN.

Microscopic Examination

#1 Microscopic examination performed.

Final Diagnosis

#1 LEFT KIDNEY, PARTIAL NEPHRECTOMY: CLEAR CELL RENAL CELL CARCINOMA.

Printed by:
Printed on:

Page 1 of 2
(Continued)

ICD-0-3
Carcinoma, renal cell
clear cell 8312/3
Site L4 kidney NOS
C64.9
JW 7/22/13

[page 2 of 2]
Surgical Pathology Report

* Final Report *

TUMOR SIZE: 3.0 CM.
SARCOMATOID FEATURES: NOT IDENTIFIED.
TUMOR NECROSIS: NOT IDENTIFIED.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 2.
LYMPH VASCULAR INVASION: NOT IDENTIFIED.
PERINEPHRIC ADIPOSE TISSUE STATUS: NEGATIVE FOR CARCINOMA.
PERINEPHRIC ADIPOSE TISSUE (RADIAL) SURGICAL MARGIN STATUS: NEGATIVE.
RENAL PARENCHYMAL MARGIN: NEGATIVE (0.1-0.2CM).
PATHOLOGIC STAGE (TNM CLASSIFICATION): pT1a.

Signature Line

Signed by: [REDACTED]
ELECTRONIC SIGNATURE

Ordering Provider

Ordering Physician: [REDACTED]

Printed by: [REDACTED]
Printed on:

Page 2 of 2
(End of Report)

Reviewed: [Signature]	Date Reviewed: 7/2/13	

Source: NCI Genomic Data Commons file 941fca0e-6be0-41fb-81eb-7b71fad7f7d5 (TCGA-A3-A6NN.80EEFFC7-47BF-4DA1-AF7C-798A1AB35C65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).